Somatic mutation profile of tumor specimen 0DSBYF from CCDI case PBCHPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 16.5 years (6,010 days).
Specimen 0DSBYF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23375abd-0a68-4e75-8f0f-bc335a0677ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSBY6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed22bfaf-de24-4444-8c67-20fdc65fed71

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 3, Intron 3, RNA 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAT | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 185/589 reads (31%) | catalogued as rs118203916, CM920663, COSV63533110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 258/1231 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as rs560601619; called by muse, varscan2
- C5orf49 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 58/642 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs750048060, COSV57874822; called by muse, mutect2
- FRG2C | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 103/993 reads (10%) | catalogued as rs1229923909; called by muse, mutect2, varscan2
- LAMA3 | c.7814G>A p.G2605D (on ENST00000313654 / NM_198129.4; = p.G996D on NM_000227.6) | Missense Mutation (SNP) | VAF 209/683 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770923157; called by muse, mutect2, varscan2
- MAP7 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 78/418 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369036954; called by muse, mutect2, varscan2
- MPP2 | c.1315C>T p.R439C (on ENST00000461854 / NM_001278372.2; = p.R415C on NM_005374.5) | Missense Mutation (SNP) | VAF 220/506 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs199836068; called by muse, mutect2, varscan2
- NMNAT1 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 118/421 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV101020449; called by muse, mutect2, varscan2
- SLC10A3 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.487); catalogued as rs782354005; called by muse, mutect2
- TRIM4 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 114/453 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV62470789; called by muse, mutect2, varscan2
- ZNF516 | c.1316G>T p.W439L | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs867518918; called by muse, mutect2, varscan2
- CYP11A1 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIN2D | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEFH | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- PCDH11Y | c.1567A>G p.T523A (on ENST00000400457 / NM_032973.2; = p.T512A on NM_032971.3) | Missense Mutation (SNP) | VAF 18/578 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); called by muse, mutect2
- PHACTR3 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 170/605 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- POM121 | c.2969G>C p.S990T (on ENST00000434423; = p.S725T on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PTPRN2 | c.2185dup p.H729Pfs*55 | Frame Shift Ins (INS) | VAF 99/321 reads (31%) | called by mutect2, varscan2
- SKIV2L | c.236+1G>A p.X79_splice | Splice Site (SNP) | VAF 60/894 reads (7%) | called by muse, mutect2
- SLC39A2 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- USP17L4 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by mutect2, varscan2
- USP28 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 105/556 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- COL15A1 | c.2499G>T p.L833= | Silent (SNP) | VAF 120/762 reads (16%) | catalogued as rs748239972; called by muse, mutect2, varscan2
- COL27A1 | c.447C>T p.L149= | Silent (SNP) | VAF 102/481 reads (21%) | catalogued as rs764478171; called by muse, mutect2, varscan2
- CSMD1 | c.8667C>T p.S2889= (on ENST00000520002; = p.S2888= on NM_033225.6) | Silent (SNP) | VAF 213/655 reads (33%) | catalogued as rs764844061, COSV59377743; called by muse, mutect2, varscan2
- GPR155 | c.921G>A p.V307= | Silent (SNP) | VAF 183/636 reads (29%) | catalogued as COSV55037024; called by muse, mutect2, varscan2
- ITPR1 | c.3639C>T p.A1213= (on ENST00000354582; = p.A1198= on NM_002222.7) | Silent (SNP) | VAF 164/529 reads (31%) | catalogued as rs763869150, COSV56985453; called by muse, mutect2, varscan2
- MARCO | c.1443C>A p.I481= | Silent (SNP) | VAF 24/854 reads (3%) | catalogued as rs1336567188; called by muse, mutect2
- ZNF451 | c.2583G>A p.E861= | Silent (SNP) | VAF 158/629 reads (25%) | called by muse, mutect2, varscan2
- AC007568.1 | n.375A>G | RNA (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- AC087379.2 | n.268G>T | RNA (SNP) | VAF 125/442 reads (28%) | called by muse, mutect2, varscan2
- HLCS | c.-392-4334C>T | Intron (SNP) | VAF 31/78 reads (40%) | catalogued as rs956554035; called by muse, mutect2, varscan2
- TVP23A | c.90-61G>A | Intron (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2, varscan2
- UQCRB | c.91+69T>C | Intron (SNP) | VAF 160/585 reads (27%) | called by muse, mutect2, varscan2
